Somatic mutation profile of tumor specimen TCGA-AB-2910-03A (aliquot TCGA-AB-2910-03A-01W-0745-08) from TCGA case TCGA-AB-2910, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute monocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.1 years (22,311 days).
Specimen TCGA-AB-2910-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f4506fd-adf9-4a98-9a31-9e0285027a19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2910-11A (Solid Tissue Normal), aliquot TCGA-AB-2910-11A-01W-0745-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/932581f5-bf34-4b33-a0f3-eb16297b2ebc

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>C p.D835H | Missense Mutation (SNP) | VAF 42/147 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCDC141 | c.4166G>A p.R1389Q | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs368802405, COSV55368595; called by muse, varscan2
- CIC | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 84/215 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs772636832, COSV50558199, COSV50581207; called by muse, mutect2, varscan2
- GTF2H1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 122/324 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.255); catalogued as COSV99786357; called by muse, mutect2, varscan2
- KCNE3 | c.83A>G p.N28S | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs772286478, COSV59551944; called by muse, mutect2, varscan2
- VWF | c.2032G>C p.E678Q | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.503); catalogued as COSV99778383; called by muse, varscan2
- WEE2 | c.1562A>T p.Q521L | Missense Mutation (SNP) | VAF 111/317 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV66879109; called by muse, mutect2, varscan2
- ZBTB7B | c.310G>A p.E104K (on ENST00000292176; = p.E138K on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV52692915, COSV52693144; called by muse, mutect2, varscan2
- ATF7IP | c.2811_2814del p.N937Kfs*3 | Frame Shift Del (DEL) | VAF 42/188 reads (22%) | called by pindel, varscan2
- SLC23A1 | c.1341G>A p.L447= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
